CGCI case BLGSP-71-30-00637 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2e96df6a-0b97-437c-9fd5-93c8fc5c13a5

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 27 years; Vital status: Alive.

Diagnoses (2)
1. Burkitt lymphoma, NOS (Includes all variants) (the primary disease): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Overlapping lesion of digestive system; Classification of tumor: primary; Age at diagnosis: 27.6 years (10,073 days); Year of diagnosis: 2005; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 5,768 days (15.8 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, adult; Max tumor bulk site: Small intestine; Sites of involvement: Peripheral blood / Small intestine.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Mesenteric; Lymph nodes positive: 1; Lymph nodes tested: 1; Tumor largest dimension diameter: 3.5 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-IVAC; Days to treatment start: 11 days; Days to treatment end: 36 days; Number of cycles: 2; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CODOX; Days to treatment start: 11 days; Days to treatment end: 36 days; Number of cycles: 2; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Cytarabine + Doxorubicin + Etoposide + Ifosfamide + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 11 days; Days to treatment end: 36 days; Number of cycles: 2; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Initial disease status: Initial Diagnosis; Days to treatment start: 102 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.
2. Tumor, NOS: Tissue or organ of origin: Intestinal tract, NOS; Classification of tumor: Synchronous primary; Age at diagnosis: 41.6 years (15,199 days); Days to diagnosis: 5,126 days (14.0 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: Radiation Therapy, NOS, for initial diagnosis; Surgery, NOS, for initial diagnosis.

Follow-up (4 entries)
- Days to follow up: 0 days; ECOG performance status: 3.
- Days to follow up: 5,397 days (14.8 years); Disease response: Tumor Free.
- Days to follow up: 5,768 days (15.8 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 5,642.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MIB1 (IHC): Positive.
- MYC translocation (FISH): Abnormal, NOS.
- Test (IHC): Negative; Specialized molecular test: CD21.
- Test (IHC): Negative; Specialized molecular test: EBV.
- Lactate Dehydrogenase 130 [Blood test normal range upper: 210].

Other clinical attributes
- Day 0: Weight: 70.6 kg; Height: 172 cm; BMI: 23.9.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-30-00637-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Other; Preservation method: FFPE; Days to sample procurement: 0 days; Method of sample procurement: Excisional Biopsy; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00637-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Biospecimen anatomic site: Gastrointestinal Tract.
- Sample BLGSP-71-30-00637-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-30-00637-01-BCL6: Tissue microarray coordinates: A1,B1.
  Slide BLGSP-71-30-00637-01-BCL2: Tissue microarray coordinates: A1,B1.
  Slide BLGSP-71-30-00637-01-EBER: Tissue microarray coordinates: A1,B1.
  Slide BLGSP-71-30-00637-01-CD20: Tissue microarray coordinates: A1,B1.
  Slide BLGSP-71-30-00637-01-CD10: Tissue microarray coordinates: A1,B1.
  Slide BLGSP-71-30-00637-01-CD3: Tissue microarray coordinates: A1,B1.
  Slide BLGSP-71-30-00637-01-Ki67: Tissue microarray coordinates: A1,B1.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 2; Lymph nodes examined: Yes.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Peripheral Blood.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 130; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: MIB-1.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD21.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: EBV.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
- New tumor event: New tumor event type: New Primary Tumor; New tumor event site other: Bowel; New tumor event diagnosis evidence: Biopsy with Histologic Confirmation; New tumor event diagnosis evidence: Convincing Imaging; New tumor event diagnosis evidence: Positive Biomarker(s); New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 1: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: Yes.
- Treatments, Treatment 1: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CODOXR/IVACR (Magrath protocol); Pharma adjuvant cycles count: 2.
- Treatments, Treatment 2: Therapy regimen: Initial; Treatment type: Stem Cell Transplant; Stem cell transplantation: Autologous.

Additional fields from the CGCI biospecimen supplement workbook CGCI-BLGSP_biospecimenSupplementSpreadsheet_TWIST_20220304.xlsx (sheet Sheet1), for sample BLGSP-71-30-00637-01A-01E-0001-01:
- % tumour: 95
